Somatic mutation profile of tumor specimen TCGA-DJ-A1QE-01A (aliquot TCGA-DJ-A1QE-01A-21D-A14W-08) from TCGA case TCGA-DJ-A1QE, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 62.0 years (22,645 days).
Specimen TCGA-DJ-A1QE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec1c7dce-4407-4e6f-997c-0a8adc65f8c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QE-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QE-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fed2dee4-ef52-4e06-ad49-3fa68c18a532

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- APBB1 | c.1637A>G p.Y546C | Missense Mutation (SNP) | VAF 176/378 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.953); catalogued as rs1216570107, COSV54976111; called by muse, mutect2, varscan2
- ITGA3 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV50312294; called by muse, mutect2, varscan2
- MED16 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54126583; called by muse, mutect2, varscan2
- MMP17 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1566095320, COSV62179429; called by muse, mutect2
- PLA1A | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs753363283, COSV56331872; called by muse, mutect2
- PRPF8 | c.4333T>G p.Y1445D | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59263554; called by muse, mutect2, varscan2
- RPL22L1 | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV55556909; called by muse, mutect2, varscan2
- SPAM1 | c.1203C>G p.N401K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56144020; called by muse, mutect2, varscan2
- TOGARAM1 | c.5044T>C p.S1682P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV63892224; called by muse, mutect2, varscan2
- USP51 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV72351660, COSV72351761; called by muse, mutect2, varscan2
- DHH | c.466_471dup p.R156_N157dup | In Frame Ins (INS) | VAF 35/94 reads (37%) | called by mutect2, varscan2
- ARSL | c.954G>T p.L318= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as COSV66965281; called by muse, mutect2, varscan2
- EXT1 | c.1989T>C p.A663= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV65479697; called by muse, mutect2, varscan2
- PHF7 | c.453A>G p.Q151= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs758873516, COSV59980170; called by muse, mutect2, varscan2
